Somatic mutation profile of tumor specimen PCProject_0256_T1B_WES (aliquot PCProject_0256_T1B_WES_1) from CMI case PCProject_0256, project CMI-MPC: Count Me In (CMI): The Metastatic Prostate Cancer (MPC) Project. Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 49.2 years (17,965 days).
Specimen PCProject_0256_T1B_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Prostate; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 339abfb6-c3eb-4d20-a529-0b86b521bbc8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen PCProject_0256_SALIVA (Saliva), aliquot PCProject_0256_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d8dae0ec-bcd9-4b88-8493-b896627483e8

The open-access MAF lists 56 somatic variants for this specimen: 37 protein-altering or splice-affecting, 15 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 15, Intron 2, Nonsense Mutation 2, RNA 1, Frame Shift Del 1, In Frame Del 1, 5'UTR 1, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.797G>T p.G266V | Missense Mutation (SNP) | VAF 122/210 reads (58%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs193920774, CM1414506, COSV52664019, COSV52666760, COSV53585299; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ACSL5 | c.1241G>A p.R414H (on ENST00000354273; = p.R470H on NM_016234.3) | Missense Mutation (SNP) | VAF 21/181 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.159); catalogued as rs750810266, COSV100634750; called by muse, mutect2, varscan2
- ADRA1A | c.250G>A p.A84T | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.918); catalogued as rs765619798, COSV52363407; called by mutect2, varscan2
- CAMK4 | c.281_283del p.L94del | In Frame Del (DEL) | VAF 41/164 reads (25%) | catalogued as rs763153246; called by pindel, varscan2
- CAMK4 | c.1257G>C p.K419N | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as COSV99998766; called by muse, mutect2, varscan2
- CCDC112 | c.585C>A p.H195Q | Missense Mutation (SNP) | VAF 24/184 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as COSV101100436; called by muse, mutect2, varscan2
- DENND2C | c.2150C>T p.P717L (on ENST00000393274 / NM_001256404.2; = p.P660L on NM_198459.4) | Missense Mutation (SNP) | VAF 61/170 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757490817, COSV101283976, COSV67920372; called by muse, mutect2, varscan2
- GABRG2 | c.1171G>T p.V391L (on ENST00000361925 / NM_001375343.1; = p.V351L on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/503 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.068); catalogued as COSV62720882; called by muse, mutect2
- H3C4 | c.397G>T p.G133W | Missense Mutation (SNP) | VAF 34/370 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV100587291; called by muse, mutect2
- HCN1 | c.2459C>T p.T820M | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.067); catalogued as COSV57503237; called by muse, mutect2, varscan2
- LPA | c.2734G>A p.A912T | Missense Mutation (SNP) | VAF 108/410 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV100306913; called by muse, mutect2, varscan2
- RIMS2 | c.4718C>T p.T1573I (on ENST00000666250 / NM_001348490.2; = p.T1144I on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 70/240 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51661128; called by muse, mutect2, varscan2
- SPATA18 | c.1492C>T p.R498* | Nonsense Mutation (SNP) | VAF 38/159 reads (24%) | catalogued as rs80047767, COSV54646538; called by muse, mutect2, varscan2
- TPST1 | c.1039C>T p.R347* | Nonsense Mutation (SNP) | VAF 50/141 reads (35%) | catalogued as COSV100507438, COSV59176067; called by muse, mutect2, varscan2
- UNC5B | c.1813G>T p.V605L | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.113); catalogued as COSV58980631; called by muse, mutect2, varscan2
- ZDHHC8 | c.1687C>T p.R563C | Missense Mutation (SNP) | VAF 54/65 reads (83%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as rs745468471; called by muse, mutect2, varscan2
- ZNF609 | c.276G>T p.R92S | Missense Mutation (SNP) | VAF 38/382 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV58580634; called by muse, mutect2
- ADGRL3 | c.3562T>A p.F1188I (on ENST00000506720 / NM_001322402.2; = p.F1120I on NM_015236.6) | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- AP5Z1 | c.700G>A p.D234N | Missense Mutation (SNP) | VAF 9/179 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2
- CYTH2 | c.166_167+14del p.X56_splice | Splice Site (DEL) | VAF 8/74 reads (11%) | called by mutect2, pindel
- DCP1A | c.1001G>A p.S334N | Missense Mutation (SNP) | VAF 21/166 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0.127); called by mutect2, varscan2
- FCGRT | c.380C>T p.S127L | Missense Mutation (SNP) | VAF 47/124 reads (38%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- KCND2 | c.180A>T p.E60D | Missense Mutation (SNP) | VAF 106/235 reads (45%) | SIFT tolerated (0.84); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KIAA1109 | c.3023_3026del p.G1008Vfs*5 | Frame Shift Del (DEL) | VAF 37/99 reads (37%) | called by mutect2, pindel, varscan2
- LCP2 | c.682G>T p.A228S | Missense Mutation (SNP) | VAF 18/298 reads (6%) | SIFT tolerated (0.51); PolyPhen benign (0.007); called by muse, mutect2
- MRC1 | c.2366C>T p.P789L | Missense Mutation (SNP) | VAF 97/374 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- MTOR | c.5971G>A p.A1991T | Missense Mutation (SNP) | VAF 15/256 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2
- NRK | c.25G>A p.D9N | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- OR10H5 | c.172C>G p.P58A | Missense Mutation (SNP) | VAF 50/137 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- POU4F1 | c.866T>C p.V289A | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.374); called by muse, mutect2, varscan2
- RUFY3 | c.782T>C p.L261P | Missense Mutation (SNP) | VAF 12/232 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- SMR3A | c.101C>T p.P34L | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- SNTG1 | c.820dup p.I274Nfs*18 | Frame Shift Ins (INS) | VAF 44/148 reads (30%) | called by mutect2, varscan2
- TRAV25 | c.207G>T p.K69N | Missense Mutation (SNP) | VAF 9/135 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); called by muse, mutect2
- UBA7 | c.221C>T p.A74V | Missense Mutation (SNP) | VAF 43/93 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- WASHC5 | c.503C>T p.S168F | Missense Mutation (SNP) | VAF 132/428 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); called by muse, varscan2
- ZNF217 | c.238C>T p.L80F | Missense Mutation (SNP) | VAF 8/153 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- AMER3 | c.2361C>T p.H787= | Silent (SNP) | VAF 63/147 reads (43%) | catalogued as rs759678765; called by muse, mutect2, varscan2
- DTX2 | c.465C>T p.N155= | Silent (SNP) | VAF 18/337 reads (5%) | called by muse, mutect2
- FCN1 | c.843C>T p.A281= | Silent (SNP) | VAF 99/350 reads (28%) | catalogued as rs775655624; called by muse, mutect2, varscan2
- HMCN1 | c.6813G>A p.A2271= | Silent (SNP) | VAF 101/287 reads (35%) | catalogued as rs181852740, COSV99633092; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MROH5 | c.2505G>T p.L835= | Silent (SNP) | VAF 38/77 reads (49%) | catalogued as rs772237977; called by muse, mutect2, varscan2
- NECTIN2 | c.855C>T p.V285= | Silent (SNP) | VAF 53/133 reads (40%) | catalogued as rs1419409974; called by muse, mutect2, varscan2
- NFIA | c.831C>T p.R277= | Silent (SNP) | VAF 22/141 reads (16%) | called by muse, mutect2, varscan2
- NLRP9 | c.2925A>G p.S975= | Silent (SNP) | VAF 15/66 reads (23%) | called by muse, mutect2, varscan2
- NOTCH1 | c.1752C>T p.V584= | Silent (SNP) | VAF 16/229 reads (7%) | catalogued as rs902251832, COSV53034054; ClinVar: likely benign; called by muse, mutect2
- NRG3 | c.906C>T p.G302= | Silent (SNP) | VAF 57/242 reads (24%) | catalogued as COSV64564815, COSV64584431; called by muse, mutect2, varscan2
- PIK3AP1 | c.621G>A p.A207= | Silent (SNP) | VAF 42/123 reads (34%) | catalogued as rs1303544999, COSV100225643, COSV59532119; called by muse, mutect2, varscan2
- RANBP17 | c.2112C>T p.F704= | Silent (SNP) | VAF 18/72 reads (25%) | catalogued as COSV101206125; called by muse, mutect2, varscan2
- RIC8B | c.1562A>G p.*521= | Silent (SNP) | VAF 10/150 reads (7%) | called by muse, mutect2
- SLC6A15 | c.1221T>C p.Y407= | Silent (SNP) | VAF 12/190 reads (6%) | catalogued as rs1487580863; called by muse, mutect2
- TECPR1 | c.3441G>A p.S1147= | Silent (SNP) | VAF 72/158 reads (46%) | catalogued as rs775175455; called by muse, mutect2, varscan2
- BRD2 | c.-826C>T | 5'UTR (SNP) | VAF 17/58 reads (29%) | catalogued as rs1350052533; called by muse, mutect2, varscan2
- COL4A3 | c.325-18G>A | Intron (SNP) | VAF 23/385 reads (6%) | called by muse, mutect2
- FMO9P | n.630-560C>A | Intron (SNP) | VAF 11/155 reads (7%) | called by muse, mutect2
- MGAT4FP | n.1125T>C | RNA (SNP) | VAF 6/52 reads (12%) | called by muse, mutect2
